Gene-level copy-number profile of tumor specimen C3L-01051-02 from CPTAC case C3L-01051, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.8 years (22,192 days).
Specimen C3L-01051-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d17ab2a-86da-4198-a4d7-8974d1f8ff5f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01051-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/435faa51-0c35-40a9-82f0-7dedf2c4c992

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,852; copy number 2: 54,836; copy number 3: 1,107; copy number 4: 48; copy number 5: 43; copy number 7: 27.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,564,029–43,308,826, 34 genes, copy number 5–7 (within-gene range 3–7): UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3.
- chr6:43,509,702–43,562,419, 1 gene, copy number 5 (within-gene range 3–5): POLR1C.
- chr6:43,519,180–44,089,288, 19 genes, copy number 5 (within-gene range 2–5): AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2.
- chr8:134,477,788–134,979,279, 16 genes, copy number 5: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
